Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8372, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8372-01A (Primary Tumor).

[page 1 of 3]
[REDACTED] Case ID	Gross Description	Microscopic Description
[REDACTED]		

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
		STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 9 x 7 x 6.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma, intestinal type Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Omentum Lymph nodes: 8/17 positive for metastasis (Intraabdominal 8/17) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
	ID	Excision Date	Laterality

Source: NCI Genomic Data Commons file aa6b2eb4-2532-4176-a7a6-99fd696aca4a (TCGA-BR-8372.7E36A66E-5969-47F3-AFE0-60A103978D4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).